Gene-level copy-number profile of tumor specimen C3L-01925-07 from CPTAC case C3L-01925, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage IV; FIGO stage: Stage IV; Tumor grade: G3; Age at diagnosis: 65.4 years (23,870 days).
Specimen C3L-01925-07: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file ea64194d-7207-4d13-becc-92756a50a40b.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-01925-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,244 have no estimate.
https://portal.gdc.cancer.gov/files/bfaf0b74-e497-452a-b65e-9b1e501a2272

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 3; copy number 2: 2,018; copy number 3: 75; copy number 4: 27,268; copy number 5: 3,010; copy number 6: 21,058; copy number 7: 861; copy number 8: 2,600; copy number 9: 234; copy number 10: 836; copy number 11: 44; copy number 12: 74; copy number 13: 60; copy number 14: 75; copy number 16: 54; copy number 17: 2; copy number 20: 74; copy number 29: 1; copy number 76: 16; copy number 125: 15.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:76,531,319–76,541,459, 1 gene (within-gene range 0–1): SPDYE16.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,485 genes in 32 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:16,352,575–16,398,145, 2 genes, copy number 10 (within-gene range 4–10): SZRD1, RPL22P3.
- chr1:44,405,194–44,986,722, 24 genes, copy number 10 (within-gene range 6–10): RNF220, MIR5584, TMEM53, ARMH1, RNU5F-1, RNU5D-1, KIF2C, AL592166.1, RPS8, SNORD55, SNORD46, SNORD38A, SNORD38B, SNORD38B, RPS15AP11, BEST4, PLK3, TCTEX1D4, BTBD19, PTCH2, RNU5E-6P, AL136380.1, EIF2B3, RNA5SP47.
- chr1:150,548,562–151,249,536, 44 genes, copy number 12: ADAMTSL4-AS2, ADAMTSL4, MIR4257, ADAMTSL4-AS1, MCL1, RN7SL473P, RN7SL600P, AL356356.1, ENSA, U4, GOLPH3L, HORMAD1, RNU6-1042P, CTSS, AL356292.1, CTSK, UBE2D3P3, ARNT, RNU6-1309P, RPS27AP6, CTXND2, CYCSP51, SETDB1, CERS2, AL590133.2, AL590133.1, ANXA9, MINDY1, PRUNE1, RNU6-884P, BNIPL, C1orf56, CDC42SE1, MLLT11, GABPB2, RPS29P29, AL592424.1, SEMA6C, TNFAIP8L2, SCNM1, LYSMD1, TMOD4, VPS72, PIP5K1A.
- chr1:155,335,268–156,615,288, 63 genes, copy number 13–20 (broad region; genes not listed).
- chr2:85,133,392–85,905,199, 41 genes, copy number 9: TCF7L1, TCF7L1-IT1, RNU6-674P, SNRPEP11, AC093162.1, TGOLN2, Y_RNA, PEBP1P2, RETSAT, ELMOD3, AC062037.1, Y_RNA, RN7SL113P, AC062037.2, CAPG, AC062037.3, SH2D6, Y_RNA, RN7SL251P, Y_RNA, RPSAP22, MAT2A, GGCX, VAMP8, RN7SL126P, VAMP5, RNF181, TMEM150A, USP39, C2orf68, SFTPB, GNLY, GPR160P1, RNU1-38P, ATOH8, MIR6071, AC105053.1, RN7SKP83, ST3GAL5, ST3GAL5-AS1, AC012511.1.
- chr3:49,716,829–50,292,918, 34 genes, copy number 9 (within-gene range 6–9): AMIGO3, GMPPB, IP6K1, COX6CP14, AC139451.1, CDHR4, INKA1, UBA7, MIR5193, TRAIP, CAMKV, RN7SL217P, ACTBP13, MST1R, AC105935.2, AC105935.1, MON1A, RBM6, RBM5, RBM5-AS1, SEMA3F-AS1, SEMA3F, AC104450.1, GNAT1, SLC38A3, GNAI2, MIR5787, U73169.1, U73166.1, SEMA3B-AS1, SEMA3B, MIR6872, LSMEM2, IFRD2.
- chr3:117,672,154–117,997,592, 1 gene, copy number 10 (within-gene range 6–10): AC092691.1.
- chr3:117,678,693–117,794,384, 2 genes, copy number 10: LINC02024, AC092691.3.
- chr3:168,858,659–169,038,416, 5 genes, copy number 10: RPL21P43, LINC02082, AC092954.1, AC092954.2, LINC01997.
- chr4:1,550,284–2,069,089, 16 genes, copy number 11–13: AC147067.2, AC147067.1, FAM53A, Y_RNA, SLBP, AC016773.1, TACC3, TMEM129, FGFR3, LETM1, NSD2, SCARNA22, NELFA, MIR943, C4orf48, NAT8L.
- chr6:47,231,532–47,309,905, 1 gene, copy number 9: TNFRSF21.
- chr6:157,381,133–158,168,280, 12 genes, copy number 12: ZDHHC14, MIR3692, SNX9, AL391863.2, AL391863.1, SNX9-AS1, HSPE1P26, RNU6-786P, SYNJ2, AL139330.1, SYNJ2-IT1, SERAC1.
- chr8:29,864,644–30,043,908, 6 genes, copy number 10: AC131254.3, AC131254.2, LINC02209, MIR3148, MAP2K1P1, RNU6-1218P.
- chr8:80,034,745–80,231,232, 1 gene, copy number 9 (within-gene range 6–9): TPD52.
- chr8:80,204,606–80,484,481, 6 genes, copy number 9 (within-gene range 6–9): RN7SL41P, MIR5708, AC104212.3, AC034114.2, AC104212.2, AC104212.1.
- chr9:128,149,071–128,446,628, 20 genes, copy number 10: LCN2, C9orf16, CIZ1, DNM1, MIR199B, MIR3154, GOLGA2, SWI5, TRUB2, AL359091.3, COQ4, SLC27A4, TMSB4XP4, URM1, AL359091.1, MIR219A2, MIR219B, CERCAM, AL359091.4, AL359091.2.
- chr11:46,332,905–46,846,308, 18 genes, copy number 12: DGKZ, MIR4688, MDK, CHRM4, AMBRA1, AC024293.1, MIR3160-1, MIR3160-2, AC127035.1, HARBI1, ATG13, ARHGAP1, ZNF408, F2, CKAP5, MIR5582, AC115088.1, SNORD67.
- chr11:55,602,360–55,652,854, 3 genes, copy number 11: OR4C11, OR4P4, OR4S2.
- chr14:18,333,726–19,003,752, 30 genes, copy number 9: CR383658.1, RNU6-458P, CR383658.2, BNIP3P6, CR383656.10, CR383656.7, CR383656.13, CR383656.9, OR11H12, CR383656.6, ARHGAP42P5, LINC02297, CR383656.5, CR383656.1, CR383656.12, CR383656.8, CR383656.11, CR383656.3, RPL22P20, CR383656.4, CR383656.2, NF1P10, NEK2P1, NF1P7, MED15P1, AL929601.1, AL929601.2, POTEM, AL929601.3, RNU6-1239P.
- chr14:101,948,347–102,305,190, 9 genes, copy number 10: AL118558.3, AL118558.4, DYNC1H1, AL118558.2, AL118558.1, RN7SL472P, HSP90AA1, WDR20, MOK.
- chr14:103,561,896–104,180,894, 27 genes, copy number 11 (within-gene range 6–11): KLC1, COA8, AL139300.1, RNU4-68P, AL049840.2, AL049840.6, AL049840.3, AL049840.4, AL049840.5, XRCC3, ZFYVE21, Y_RNA, PPP1R13B, AL049840.7, AL049840.1, LINC00637, AL132712.1, AL132712.2, ATP5MPL, TDRD9, RD3L, RN7SL634P, ASPG, MIR203A, MIR203B, AL359399.1, KIF26A.
- chr15:21,293,653–21,325,241, 3 genes, copy number 17–29 (within-gene range 11–29): AC068446.1, AC068446.2, RNU6-1235P.
- chr16:287,440–800,737, 49 genes, copy number 10: AXIN1, MRPL28, PGAP6, Z97634.1, NME4, DECR2, AL023881.1, RAB11FIP3, Y_RNA, AL049542.1, LINC00235, CAPN15, MIR5587, MIR3176, Z97986.1, PRR35, PIGQ, NHLRC4, Z98883.1, RAB40C, WFIKKN1, METTL26, MCRIP2, AL022341.1, WDR90, AL022341.2, RHOT2, RHBDL1, LINC02867, Z92544.2, STUB1, JMJD8, WDR24, Z92544.1, FBXL16, Z97653.2, Z97653.1, METRN, ANTKMT, CCDC78, HAGHL, CIAO3, MSLN, AL031258.1, MSLNL, MIR662, RPUSD1, CHTF18, GNG13.
- chr16:1,064,093–1,078,731, 1 gene, copy number 10 (within-gene range 7–10): SSTR5-AS1.
- chr16:1,078,781–1,612,072, 49 genes, copy number 10 (within-gene range 10–15): SSTR5, C1QTNF8, AL031713.1, AL031598.1, AC120498.8, CACNA1H, AC120498.3, AC120498.1, AC120498.6, TPSG1, AC120498.10, TPSB2, TPSAB1, TPSD1, AC120498.2, PRSS29P, AC120498.7, AC120498.5, TPSP2, AC120498.4, AC120498.9, UBE2I, AL031714.1, RPS20P2, BAIAP3, TSR3, GNPTG, AL031709.1, UNKL, AL032819.1, C16orf91, PERCC1, CCDC154, AL032819.2, CLCN7, AL031600.3, AL031600.1, AL031600.2, RPS3AP2, PTX4, TELO2, IFT140, AL031705.1, TMEM204, AL031719.1, AL031719.2, Z97633.1, AL133297.1, AL133297.2.
- chr17:18,390,153–18,400,961, 2 genes, copy number 11: AL353997.5, TBC1D3P4.
- chr17:18,450,244–18,506,313, 6 genes, copy number 9–10: KRT16P4, AL353997.1, AL353997.4, TNPO1P2, LGALS9C, NOS2P2.
- chr17:39,461,486–42,021,376, 163 genes, copy number 10–125 (within-gene range 4–125) (broad region; genes not listed).
- chr17:58,692,573–63,886,411, 172 genes, copy number 10–16 (broad region; genes not listed).
- chr17:64,477,785–82,212,830, 551 genes, copy number 10–14 (broad region; genes not listed).
- chr19:9,604,680–11,619,161, 119 genes, copy number 9 (broad region; genes not listed).
- chr19:12,224,686–12,365,905, 5 genes, copy number 11 (within-gene range 2–11): ZNF44, AC012618.1, AC012618.2, ZNF563, ZNF442.

Autosomal genes at a single copy (total copy number 1): 3. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
